Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3509, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3509-01A (Primary Tumor).

*** Diagnosis / Diagnoses: ***

- 1.: Small specimen with submesothelial fibrosis excised from the peritoneum.
- 2.: Resectate from a portion of the colon (sigmoid) with an ulcerated colon carcinoma, of the histological type of a moderately differentiated colon carcinoma, that extends no closer than 3 cm to the resection margin and occupies a circular portion of the intestinal wall over an length of 5 cm. Invasive spread of the tumor within all layers of the intestinal wall as far as the neighboring mesocolic fatty tissue.
Oral and aboral resection margin tumor-free.
27 mesocolic lymph nodes tumor-free, with uncharacteristic reactive changes.

The tumor stage is thus pT3 pN0 (1/27), L0, V0, R0; G2

Source: NCI Genomic Data Commons file e9a00dab-0a01-438c-b33f-a2a2cf8a088c (TCGA-AA-3509.82C6FF26-495D-4E6A-B00C-CD4CE99E55D1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).